CCDI case PBCABN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/942823dd-4db3-410b-baa0-6fdd42d6927a

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; Tissue or organ of origin: Ovary; Age at diagnosis: 13.4 years (4,900 days).

Biospecimens (2 samples)
- Sample 0DM1JF: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DM1JZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
